Somatic mutation profile of tumor specimen 0DEV4C from CCDI case PBBPYI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.7 years (3,912 days).
Specimen 0DEV4C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f19ef1d4-6b81-44a5-94f5-eaeea183fe05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEV2D (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26e9de23-7965-4eb4-abaf-9ae91eaa57f9

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 122/248 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- CEP350 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 173/411 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs973419384; called by muse, varscan2
- CTXN3 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 98/404 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs780758497, COSV65218980; called by muse, varscan2
- FBLN5 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 65/231 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs138577384; called by muse, varscan2
- SMARCA4 | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs778175819, COSV60785488, COSV60786996; called by muse, varscan2
- SMARCA4 | c.3575G>T p.R1192L | Missense Mutation (SNP) | VAF 77/264 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60785906, COSV60794673; called by muse, varscan2
- LYST | c.8017G>C p.V2673L | Missense Mutation (SNP) | VAF 170/379 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, varscan2
- ZNRF3 | c.1747T>A p.C583S (on ENST00000544604 / NM_001206998.2; = p.C483S on NM_032173.3) | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); called by muse, varscan2
- ZNF865 | c.336G>A p.S112= | Silent (SNP) | VAF 70/132 reads (53%) | catalogued as COSV73830497; called by muse, varscan2
